Somatic mutation profile of tumor specimen 0DG85U from CCDI case PBBPRP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 2.1 years (770 days).
Specimen 0DG85U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d116f4f1-f6d4-4d9c-a732-ab49c4b7eba5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG84K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ffe912a-3f95-4c21-bcf3-630334741630

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 1, Frame Shift Del 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR5H15 | c.264G>T p.K88N | Missense Mutation (SNP) | VAF 288/1444 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV100736594, COSV62948556, COSV62948901; called by muse, varscan2
- RNF175 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 132/467 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs560692292, COSV56841108, COSV99924117; called by muse, varscan2
- PTCH1 | c.1351del p.A451Pfs*5 | Frame Shift Del (DEL) | VAF 138/536 reads (26%) | called by pindel, varscan2
- TTC23 | c.109C>T p.L37= | Silent (SNP) | VAF 216/692 reads (31%) | catalogued as rs111775071; called by muse, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 68/604 reads (11%) | called by muse, varscan2
- DAO | c.696-64T>C | Intron (SNP) | VAF 40/140 reads (29%) | called by muse, varscan2
